MMRF case MMRF_2195 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d31acf65-2837-4b31-8077-4a74aca5f549

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.0 years (25,569 days); ISS stage: II; Days to last known disease status: 895 days (2.5 years); Days to last follow up: 895 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 405 days (1.1 years).
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 380 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 741 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 6.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 168 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.4 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 43.9 g/L; Immunoglobulin M 1.05 g/L; Beta 2 Microglobulin 4.04 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.08 ×10⁹/L; Absolute Neutrophil 3.67 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.53 mmol/L; Albumin 36 g/L; Total Protein 11.1 g/dL; Glucose 5.61 mmol/L.
- Day 125 (ECOG 2): M Protein 1.74 g/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 9.31 g/L; Immunoglobulin M 1.09 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 6.13 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.47 ×10⁹/L; Absolute Neutrophil 2.47 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 5.83 mmol/L.
- Day 193 (ECOG 0): M Protein 1.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 8.96 g/L; Immunoglobulin A 6.69 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 6.2 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 56.6 µmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7.08 g/dL; Glucose 5.12 mmol/L.
- Day 265 (ECOG 1): M Protein 1.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 8.72 g/L; Immunoglobulin A 6.68 g/L; Immunoglobulin M 0.78 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 5.9 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.41 ×10⁹/L; Absolute Neutrophil 3.08 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 57.5 µmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.89 g/dL; Glucose 5.23 mmol/L.
- Day 349: M Protein 1.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 8.07 g/L; Immunoglobulin A 5.87 g/L; Immunoglobulin M 0.8 g/L; Beta 2 Microglobulin 2.66 µg/mL; Lactate Dehydrogenase 5.63 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 8.49 ×10⁹/L; Absolute Neutrophil 6.36 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 69.8 µmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.82 g/dL; Glucose 5.39 mmol/L.
- Day 468 (ECOG 2): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 6.31 g/L; Immunoglobulin M 0.75 g/L; Beta 2 Microglobulin 1.96 µg/mL; Lactate Dehydrogenase 5.12 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.15 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 66.3 µmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.92 g/dL; Glucose 5.67 mmol/L.
- Day 524: M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Lactate Dehydrogenase 5.48 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.36 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 56.6 µmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 7.66 g/dL; Glucose 5.67 mmol/L.
- Day 655: M Protein 0.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 9 g/L; Immunoglobulin A 6.8 g/L; Immunoglobulin M 1.08 g/L; Beta 2 Microglobulin 2.98 µg/mL; Lactate Dehydrogenase 4.6 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.91 ×10⁹/L; Absolute Neutrophil 3.95 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.78 mmol/L.
- Day 725: M Protein 2.06 g/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 16.3 g/L; Immunoglobulin M 0.88 g/L; Beta 2 Microglobulin 5.18 µg/mL; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.77 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 8.3 g/dL; Glucose 6 mmol/L.
- Day 811 (ECOG 1): Hemoglobin 6.88 mmol/L; Leukocytes 8.07 ×10⁹/L; Absolute Neutrophil 4.36 ×10⁹/L; Platelets 313 ×10⁹/L; Creatinine 85.7 µmol/L; Glucose 5.39 mmol/L.
- Day 895: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.35 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 0.81 g/L; Beta 2 Microglobulin 5.41 µg/mL; Lactate Dehydrogenase 5.13 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 8.01 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 85.7 µmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -6: Weight: 75 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_2195_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2195_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
